MMRF case MMRF_1453 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1711a2cb-96b5-4803-81b4-1987b0ccd672

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.7 years (18,883 days); ISS stage: II; Days to last known disease status: 773 days (2.1 years); Days to last follow up: 773 days (2.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 137 days; Days to treatment end: 137 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 236 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.185 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1260 mg/dL; Immunoglobulin G 3.84 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.74 µg/mL; Lactate Dehydrogenase 8.28 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 5.88 ×10⁹/L; Platelets 326 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 3.15 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 4.9 mmol/L.
- Day 75: Serum Free Immunoglobulin Light Chain, Kappa 0.132 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 16.2 mg/dL; Immunoglobulin G 2 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 7.82 ×10⁹/L; Absolute Neutrophil 6.65 ×10⁹/L; Platelets 314 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.48 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 4.51 mmol/L.
- Day 166 (ECOG 3): Serum Free Immunoglobulin Light Chain, Kappa 0.177 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.22 mg/dL; Immunoglobulin G 3.04 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 12.5 ×10⁹/L; Absolute Neutrophil 11.2 ×10⁹/L; Platelets 342 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 8.2 mmol/L.
- Day 247: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.76 mg/dL; Immunoglobulin G 8.57 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 3.27 µg/mL; Hemoglobin 8.68 mmol/L; Leukocytes 5.01 ×10⁹/L; Absolute Neutrophil 2.73 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.3 mmol/L; Albumin 46 g/L; Total Protein 7.3 g/dL; Glucose 4.9 mmol/L.
- Day 341 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.47 mg/dL; Immunoglobulin G 6.48 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.16 ×10⁹/L; Absolute Neutrophil 1.43 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 3.74 mmol/L.
- Day 442 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.944 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.47 mg/dL; Immunoglobulin G 6.58 g/L; Immunoglobulin A 1.07 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 8.99 mmol/L; Leukocytes 6.05 ×10⁹/L; Absolute Neutrophil 3.11 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 3.14 mmol/L.
- Day 528 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.3 mg/dL; Immunoglobulin G 7.3 g/L; Immunoglobulin A 1.35 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 8.99 mmol/L; Leukocytes 4.82 ×10⁹/L; Absolute Neutrophil 2.42 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 4.46 mmol/L.
- Day 618: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.11 mg/dL; Immunoglobulin G 7.62 g/L; Immunoglobulin A 1.43 g/L; Immunoglobulin M 0.08 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 5.39 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 3.85 mmol/L.
- Day 709 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.83 mg/dL; Immunoglobulin G 8.4 g/L; Immunoglobulin A 1.54 g/L; Immunoglobulin M 0.1 g/L; Hemoglobin 9.42 mmol/L; Leukocytes 5.59 ×10⁹/L; Absolute Neutrophil 2.96 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 5.89 mmol/L.
- Day 773 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.68 mg/dL; Immunoglobulin G 7.81 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 3.57 ×10⁹/L; Absolute Neutrophil 1.46 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 4.9 mmol/L.

Other clinical attributes
- Day -10: Weight: 101 kg; Height: 185 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1453_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_1453_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
